Gene-level copy-number profile of tumor specimen TCGA-NC-A5HE-01A from TCGA case TCGA-NC-A5HE, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 60.7 years (22,179 days).
Specimen TCGA-NC-A5HE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.7f64f7b3-e2eb-44e3-aabf-596db3a1b4ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NC-A5HE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00ae2557-2b08-4241-95ea-f94d33da1973

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 101; copy number 1: 25,191; copy number 2: 28,982; copy number 3: 2,189; copy number 4: 2,831; copy number 5: 470; copy number 6: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NC-A5HE-01A-11D-A26L-01): tumor purity 0.32, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–117,027,039, 5 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr8:150,584–545,781, 17 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr10:4,987,400–5,107,686, 4 genes (within-gene range 0–2): AKR1C2, AL391427.1, U8, AKR1C3.
- chr14:22,066,016–22,506,702, 65 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 525 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:210,231,456–213,579,267, 81 genes, copy number 5 (broad region; genes not listed).
- chr2:170,601,662–184,382,869, 248 genes, copy number 5 (broad region; genes not listed).
- chr2:186,032,884–192,044,525, 84 genes, copy number 5 (broad region; genes not listed).
- chr3:187,668,912–192,119,864, 50 genes, copy number 5: SST, RTP2, AC072022.1, BCL6, AC072022.2, AC108681.1, AC068295.1, LINC01991, AC092941.1, AC092941.2, AC022498.1, LPP-AS2, LPP, FLJ42393, LPP-AS1, MIR28, TPRG1-AS1, TPRG1, AC009319.1, TPRG1-AS2, TP63, AC078809.1, MIR944, P3H2, MTAPP2, P3H2-AS1, RNU6-1109P, NMNAT1P3, CLDN1, CLDN16, TMEM207, IL1RAP, GCNT1P3, RN7SKP296, AC108747.1, LINC02013, CCT6P4, AC092952.1, GMNC, OSTN, OSTN-AS1, UTS2B, CCDC50, AC073365.1, PYDC2, Y_RNA, AC026320.2, AC026320.1, AC026320.3, RN7SKP222.
- chr3:192,238,037–192,283,097, 1 gene, copy number 5: FGF12-AS1.
- chr4:95,840,093–96,818,864, 6 genes, copy number 5 (within-gene range 3–5): PDHA2, RNU6-1059P, RNU6-34P, AC096661.1, LINC02267, RN7SKP28.
- chr18:13,882,044–15,330,282, 55 genes, copy number 6: MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 22,814. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
